Gene-level copy-number profile of tumor specimen TCGA-ER-A19B-06A from TCGA case TCGA-ER-A19B, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 48.4 years (17,664 days).
Specimen TCGA-ER-A19B-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.91970176-0cb6-4049-ac85-496d75060da6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A19B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8de911bc-f8a7-4802-b40e-bfd8d2ffe585

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 594; copy number 2: 17,312; copy number 3: 25,583; copy number 4: 10,854; copy number 5: 2,669; copy number 6: 1,125; copy number 7: 1,297; copy number 8: 178; copy number 9: 3; copy number 10: 138.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A19B-06A-11D-A194-01): tumor purity 0.78, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,957,394–22,128,103, 66 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,616 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–51,919,381, 3 genes, copy number 9: DCUN1D4, DUTP7, AC027271.1.
- chr7:70,972–57,837,046, 1,078 genes, copy number 7–10 (broad region; genes not listed).
- chr7:78,486,530–78,487,028, 1 gene, copy number 10: AC007237.1.
- chr22:33,162,226–33,922,841, 1 gene, copy number 7 (within-gene range 3–7): LARGE1.
- chr22:33,436,582–50,801,309, 533 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 594. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
